Somatic mutation profile of tumor specimen TCGA-24-1424-01A (aliquot TCGA-24-1424-01A-01W-0549-09) from TCGA case TCGA-24-1424, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.2 years (24,545 days).
Specimen TCGA-24-1424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98eb7292-a122-4ea0-8246-70200efceac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1424-10A (Blood Derived Normal), aliquot TCGA-24-1424-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b808ce7-2014-4915-82ec-aba54afd60f1

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Nonsense Mutation 5, Intron 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 138/184 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 40/458 reads (9%) | catalogued as COSV101423365; called by muse, mutect2
- ALMS1 | c.6830G>C p.C2277S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100042132; called by muse, mutect2, varscan2
- AMBN | c.1016C>A p.P339Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV59826014; called by muse, mutect2, varscan2
- ARHGAP20 | c.2961C>A p.D987E | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52810308; called by muse, mutect2, varscan2
- CAMK1D | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs1322015233, COSV101123651; called by muse, mutect2, varscan2
- CASP6 | c.56T>G p.M19R | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV54460710; called by muse, mutect2, varscan2
- CEP250 | c.5660A>G p.E1887G | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs768431825, COSV61169770; called by muse, mutect2, varscan2
- CHRNA7 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769876615, COSV60970086; called by muse, mutect2, varscan2
- COL4A5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); catalogued as COSV57865205; called by muse, mutect2, varscan2
- DOCK3 | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1266769138, COSV56518549; called by muse, mutect2, varscan2
- DYSF | c.4331C>G p.P1444R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.254); catalogued as rs1367340192, COSV50513809, COSV99243330; called by muse, mutect2
- ERICH3 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV58605554; called by muse, mutect2, varscan2
- ETAA1 | c.2706A>T p.R902S | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55472858; called by muse, mutect2, varscan2
- EVI5 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100789675, COSV63278595; called by muse, mutect2, varscan2
- FAM193A | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 84/154 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV61193468; called by muse, mutect2, varscan2
- FAT3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV53104741; called by muse, mutect2, varscan2
- FUZ | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 52/610 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100571116; called by muse, mutect2
- GCNA | c.95C>G p.T32S | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs958916834, COSV101032499; called by muse, mutect2, varscan2
- GNA14 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV59022782; called by muse, mutect2, varscan2
- HAP1 | c.509C>G p.T170S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57878378; called by muse, mutect2, varscan2
- IL13 | c.152T>G p.V51G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58734178; called by muse, mutect2, varscan2
- IL1R2 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100207924; called by muse, mutect2, varscan2
- ING1 | c.1134G>T p.W378C | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58168762, COSV58171881; called by muse, mutect2, varscan2
- KHDRBS2 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV99832934; called by muse, mutect2, varscan2
- KIN | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 140/380 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV65430449; called by muse, mutect2, varscan2
- LCT | c.59C>A p.S20* | Nonsense Mutation (SNP) | VAF 54/253 reads (21%) | catalogued as COSV51466093; called by muse, mutect2, varscan2
- MAGEC2 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 118/611 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55999079; called by muse, mutect2, varscan2
- MCF2L2 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100191526, COSV100192175; called by muse, mutect2, varscan2
- MDM4 | c.917G>C p.C306S | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100914441; called by muse, mutect2
- MIB1 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV55090059; called by muse, mutect2, varscan2
- MYH4 | c.3984+1G>T p.X1328_splice | Splice Site (SNP) | VAF 27/232 reads (12%) | catalogued as COSV99701040; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 14/90 reads (16%) | catalogued as rs772439983; called by mutect2, varscan2
- NRXN1 | c.4316G>T p.R1439L | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60486364, COSV60496995; called by muse, mutect2, varscan2
- OR12D2 | c.710T>A p.L237Q | Missense Mutation (SNP) | VAF 71/601 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101011223; called by muse, mutect2, varscan2
- OR2V2 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV60315484; called by muse, mutect2, varscan2
- PCDHB13 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV53394849; called by muse, mutect2, varscan2
- RESF1 | c.5183C>A p.T1728N | Missense Mutation (SNP) | VAF 69/440 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440294; called by muse, mutect2, varscan2
- RINT1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV57558335; called by muse, mutect2, varscan2
- RUSF1 | c.462G>T p.G154= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100512376; called by muse, mutect2, varscan2
- SI | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV52276455; called by muse, mutect2
- SLC13A1 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520756; called by muse, mutect2, varscan2
- SLC4A2 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441901345, COSV52540384; called by muse, mutect2, varscan2
- SLC7A2 | c.739G>C p.G247R (on ENST00000494857 / NM_001370338.1; = p.G287R on NM_003046.6) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50251776; called by muse, mutect2, varscan2
- STBD1 | c.858C>A p.D286E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1317576621, COSV52953773; called by muse, mutect2
- STX6 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs767706483, COSV51111945; called by muse, mutect2, varscan2
- TRMT10C | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59305729; called by muse, mutect2, varscan2
- UBE2J1 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as rs145712020; called by muse, mutect2, varscan2
- UNC79 | c.3998G>A p.R1333H (on ENST00000393151 / NM_001346218.2; = p.R1156H on NM_020818.5) | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56377438, COSV56383562; called by muse, mutect2, varscan2
- UST | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV100819848; called by muse, mutect2
- VPS50 | c.2721T>G p.I907M | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59918172; called by muse, mutect2, varscan2
- CCDC141 | c.3922_3923del p.K1308Efs*10 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- GJA8 | c.759dup p.S254Lfs*126 | Frame Shift Ins (INS) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- IGLV3-21 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INSM2 | c.878G>C p.C293S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPHOSPH6 | c.193_201del p.L65_C67del | In Frame Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.1541del p.P514Qfs*43 | Frame Shift Del (DEL) | VAF 29/178 reads (16%) | called by mutect2, pindel*, varscan2
- CDH8 | c.1773C>A p.T591= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV54863981; called by muse, mutect2, varscan2
- EVI5 | c.642C>T p.N214= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV100789676; called by muse, mutect2, varscan2
- GRM3 | c.1530C>T p.S510= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs527768281, COSV64480613; called by muse, mutect2
- HSFX1 | c.9C>T p.D3= | Silent (SNP) | VAF 30/290 reads (10%) | called by muse, mutect2, varscan2
- KNSTRN | c.804G>A p.K268= | Silent (SNP) | VAF 82/371 reads (22%) | catalogued as rs1398350001, COSV51105022; called by muse, mutect2, varscan2
- MYO9B | c.2298C>G p.S766= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV101261495; called by muse, mutect2
- OR12D2 | c.709C>T p.L237= | Silent (SNP) | VAF 72/596 reads (12%) | catalogued as COSV65827704; called by muse, mutect2, varscan2
- PCDH7 | c.3027C>T p.P1009= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs759430898, COSV62338487; called by muse, mutect2, varscan2
- PCDHGB2 | c.2214G>A p.G738= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs765171901, COSV99536193; called by muse, mutect2
- PTPRT | c.2721C>T p.A907= | Silent (SNP) | VAF 64/534 reads (12%) | catalogued as COSV61978184; called by muse, mutect2, varscan2
- RD3 | c.30C>T p.N10= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs774563819, COSV65362200, COSV65362702; called by muse, mutect2, varscan2
- SFMBT2 | c.1671G>C p.P557= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs200717836, COSV62808909; called by muse, mutect2
- SLC26A4 | c.1950T>C p.V650= | Silent (SNP) | VAF 23/183 reads (13%) | catalogued as COSV55916316; called by muse, mutect2, varscan2
- TGFBR3 | c.1293C>T p.S431= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as rs1320009175, COSV53024931; called by muse, mutect2, varscan2
- TMEM266 | c.390C>T p.S130= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs761400106, COSV66379626; called by muse, mutect2, varscan2
- VCAN | c.7803A>C p.V2601= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs1184248149, COSV54103985; called by muse, mutect2, varscan2
- VWCE | c.1560G>A p.E520= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as rs540936887, COSV57112152; called by muse, mutect2, varscan2
- CREM | c.508+40T>C | Intron (SNP) | VAF 32/214 reads (15%) | catalogued as COSV100415139; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85989G>A | Intron (SNP) | VAF 39/198 reads (20%) | catalogued as COSV72276853; called by muse, mutect2, varscan2
- SLC35A2 | c.1163+86A>T | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99504217; called by muse, varscan2
